Gene-level copy-number profile of tumor specimen C3N-03190-01 (profiled together with C3N-03190-02) from CPTAC case C3N-03190, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G1; Age at diagnosis: 31.9 years (11,659 days).
Specimen C3N-03190-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f4d63709-34dc-4516-a567-4f9778a96fbf.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03190-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/fff83569-31ba-4d7a-987a-abce81dcc421

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 617; copy number 1: 12,198; copy number 2: 41,812; copy number 3: 4,267; copy number 4: 19.

Homozygous deletions (total copy number 0; autosomes only): 101 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:19,460,926–24,592,104, 88 genes (broad region; genes not listed).
- chr13:21,038,529–21,038,667, 1 gene (within-gene range 0–2): RNU4-9P.
- chr18:50,879,080–51,643,939, 12 genes: ME2, Y_RNA, ELAC1, AC091551.1, SMAD4, SRSF10P1, MEX3C, RNU1-46P, LINC01630, SS18L2P2, AC109315.1, RSL24D1P9.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 9,858. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
